Somatic mutation profile of tumor specimen 0DF6VF from CCDI case PBBRSL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.4 years (3,800 days).
Specimen 0DF6VF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7cfddee-864b-48a2-8473-7bad21036bb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF6VD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a30029ca-b27a-4b69-9dab-f6d69d42c255

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 3'UTR 1, Nonsense Mutation 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1459del p.R487Afs*8 (on ENST00000399959; = p.R488Afs*8 on NM_001356.5) | Frame Shift Del (DEL) | VAF 238/256 reads (93%) | catalogued as rs886041963, COSV67863189; ClinVar: pathogenic; called by mutect2, varscan2
- PTCH1 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 506/551 reads (92%) | catalogued as rs1554702186; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PUM1 | c.3433C>T p.R1145W | Missense Mutation (SNP) | VAF 224/605 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1557539450, COSV57086710; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GCNT2 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 157/616 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150732107; called by muse, mutect2, varscan2
- MMRN2 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 122/291 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs200264249; called by muse, mutect2, varscan2
- OSGIN2 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 202/493 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs138873812; called by muse, mutect2, varscan2
- TRIM43 | c.373A>G p.K125E | Missense Mutation (SNP) | VAF 256/735 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CHD7 | c.7596G>A p.T2532= | Silent (SNP) | VAF 202/461 reads (44%) | catalogued as rs375969680; ClinVar: likely benign; called by muse, mutect2, varscan2
- RFX1 | c.2466G>T p.A822= | Silent (SNP) | VAF 74/181 reads (41%) | catalogued as rs1186667698; called by muse, mutect2, varscan2
- ATG2B | c.-34G>A | 5'UTR (SNP) | VAF 121/298 reads (41%) | called by muse, mutect2, varscan2
- MFSD2A | c.*76C>A | 3'UTR (SNP) | VAF 10/82 reads (12%) | called by muse, varscan2
